Somatic mutation profile of tumor specimen 0DTMA0 from CCDI case PBCKAC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 3.8 years (1,384 days).
Specimen 0DTMA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5699aa42-8717-49d9-84de-d14183ec6750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTMA2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edfff23c-7809-488e-9482-310f0dee5c8b

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R3B | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 94/978 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs201461845; called by muse, mutect2
- RTL8A | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV66188463; called by muse, mutect2, varscan2
- ETNPPL | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 15/592 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MNX1 | c.691+1G>T p.X231_splice | Splice Site (SNP) | VAF 14/408 reads (3%) | called by muse, mutect2
